Somatic mutation profile of tumor specimen BA2529D (aliquot aq-BA2529D) from BEATAML1.0 case 2311, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.1 years (23,421 days).
Specimen BA2529D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db448a7-c420-44df-aca1-9dee2108eea0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2711D (Solid Tissue Normal), aliquot aq-BA2711D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08a6dcd8-6a43-4dd8-8be1-cd7947a62201

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRC73 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV99446760; called by muse, mutect2
- WDR33 | c.3818A>G p.K1273R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.099); catalogued as rs1467606091; called by muse, mutect2
- WNT3A | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as COSV52729133; called by muse, mutect2
- ALPG | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2
- MYH6 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2
- TYMS | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TRPM1 | c.1650T>A p.T550= | Silent (SNP) | VAF 17/439 reads (4%) | called by muse, mutect2
